PECGS case C083-000068 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/19da60fa-43ab-4456-99ab-b9b2ceb0b454

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 60 years; Year of birth: 1954; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Age at diagnosis: 60.3 years (22,025 days); AJCC pathologic stage: Stage IIIB; Progression or recurrence: yes; Days to last follow up: 817 days (2.2 years).

Other clinical attributes
- BMI: 28.34; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000068_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000068_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
